Somatic mutation profile of tumor specimen 0DQB2X from CCDI case PBCEXI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.0 years (6,927 days).
Specimen 0DQB2X: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3df646b-0c0b-441d-981f-c50b9e705041.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQB26 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d2cedb1-8b21-42fc-8388-afded561ac18

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAP3K9 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 35/506 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866106057, COSV67122154; called by muse, mutect2
- RSPH9 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 36/592 reads (6%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV100937758; called by muse, mutect2
- CUL9 | c.4583G>A p.S1528N | Missense Mutation (SNP) | VAF 94/594 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MAGI2 | c.3499T>A p.Y1167N | Missense Mutation (SNP) | VAF 23/652 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCOR2 | c.5313C>G p.R1771= | Silent (SNP) | VAF 113/857 reads (13%) | called by muse, mutect2, varscan2
- OCSTAMP | c.1236G>A p.A412= | Silent (SNP) | VAF 30/464 reads (6%) | catalogued as COSV99644931; called by muse, mutect2
- HGS | c.123-58G>A | Intron (SNP) | VAF 17/238 reads (7%) | catalogued as rs1474922270; called by muse, mutect2
- SLC39A4 | c.193-43C>T | Intron (SNP) | VAF 106/491 reads (22%) | called by muse, mutect2, varscan2
